Somatic mutation profile of tumor specimen TCGA-34-5234-01A (aliquot TCGA-34-5234-01A-01D-1632-08) from TCGA case TCGA-34-5234, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 71.4 years (26,072 days).
Specimen TCGA-34-5234-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c981ff4d-ebc3-412d-a31e-d98d3d5b696e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-5234-10A (Blood Derived Normal), aliquot TCGA-34-5234-10A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fed5902-6e95-4526-a119-ec4eade5576b

The open-access MAF lists 162 somatic variants for this specimen: 122 protein-altering or splice-affecting, 35 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 35, Nonsense Mutation 9, Frame Shift Del 3, RNA 3, Splice Site 2, Intron 1, Splice Region 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2B | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs754983348, COSV61657410; called by muse, mutect2
- ADAMTS12 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1255319526, COSV61260162; called by muse, mutect2, varscan2
- ADCY3 | c.2951C>T p.A984V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53166267; called by muse, mutect2, varscan2
- AFF2 | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53984343, COSV99662278; called by muse, mutect2
- AHNAK | c.3962C>T p.P1321L | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV57210015; called by muse, mutect2
- AHNAK | c.3550A>G p.K1184E | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV57210029; called by muse, mutect2
- ARSH | c.1573C>A p.P525T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); catalogued as COSV66962793; called by muse, mutect2, varscan2
- ATG2B | c.3100C>A p.R1034S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.097); catalogued as COSV63422573, COSV63424765; called by muse, mutect2, varscan2
- ATP7A | c.1364C>A p.A455D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.127); catalogued as COSV58444719; called by muse, mutect2, varscan2
- BAZ1B | c.2347G>T p.V783L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.014); catalogued as COSV59990194; called by muse, mutect2
- BCOR | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60704825; called by muse, mutect2
- C1orf53 | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV66323444; called by muse, mutect2
- C2CD5 | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV61723977; called by muse, mutect2
- CACNA1E | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62389314; called by muse, mutect2, varscan2
- CCDC15 | c.1306A>G p.K436E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.994); catalogued as COSV61081110; called by muse, mutect2, varscan2
- CFHR3 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66401912; called by muse, mutect2, varscan2
- CNGA3 | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM980379, COSV55623679; called by muse, mutect2, varscan2
- COL5A2 | c.3662G>C p.G1221A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66408087, COSV66408644; called by muse, mutect2
- CRYBG1 | c.5433A>G p.I1811M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64811623; called by muse, mutect2, varscan2
- CYBB | c.1618G>T p.E540* | Nonsense Mutation (SNP) | VAF 4/70 reads (6%) | catalogued as CD097718, COSV66085140; called by muse, mutect2
- DNAJB9 | c.38G>T p.C13F | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV50812032; called by muse, mutect2, varscan2
- DVL3 | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57455599; called by muse, mutect2, varscan2
- EDNRB | c.1555G>T p.G519* (on ENST00000377211 / NM_001201397.1; = p.G429* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100527042; called by muse, mutect2
- EFCAB11 | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV57445789; called by muse, mutect2
- EPHB3 | c.2212A>T p.M738L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV57805272; called by muse, mutect2, varscan2
- F8 | c.1814A>T p.Y605F | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM080317, CM930222, COSV64271695; called by muse, mutect2, varscan2
- FAM184A | c.2016G>T p.L672F | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs868167807, COSV58853227; called by muse, mutect2, varscan2
- FAM193A | c.2131G>T p.G711W | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100219562; called by muse, mutect2, varscan2
- FAM50A | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 9/110 reads (8%) | catalogued as COSV50130960, COSV50132982; called by muse, mutect2
- FAT1 | c.6628G>T p.E2210* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as COSV71673309; called by muse, mutect2, varscan2
- FAT4 | c.10747T>A p.Y3583N | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.549); catalogued as COSV58679126; called by muse, mutect2, varscan2
- FUNDC2 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65670709; called by muse, mutect2, varscan2
- GAB1 | c.1799A>T p.D600V | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.283); catalogued as COSV53755681, COSV53761823; called by muse, mutect2, varscan2
- GRK7 | c.1607C>A p.P536H | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.19); catalogued as COSV53822340; called by muse, mutect2
- GRXCR1 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.994); catalogued as rs1486855844, COSV67671114; called by muse, mutect2, varscan2
- HECW1 | c.2885A>C p.E962A | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV67826535; called by muse, mutect2
- HERC2 | c.3241G>C p.E1081Q | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV55317599; called by muse, mutect2
- INTS6L | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66084108; called by muse, mutect2
- IPPK | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV55333402; called by muse, mutect2, varscan2
- KANK1 | c.2574G>T p.Q858H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs751379930, COSV63211350; called by muse, mutect2, varscan2
- KCNC2 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54366482; called by muse, mutect2, varscan2
- KCNE4 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.545); catalogued as rs762566965, COSV56054261, COSV56054378; called by muse, mutect2, varscan2
- KIF2B | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs535420177, COSV52129197; called by mutect2, varscan2
- KRTAP22-1 | c.111G>T p.W37C | Missense Mutation (SNP) | VAF 15/185 reads (8%) | PolyPhen benign (0); catalogued as COSV58182132; called by muse, mutect2
- LENG8 | c.280A>G p.N94D | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV58727064; called by muse, mutect2, varscan2
- LRRK2 | c.6617A>G p.H2206R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54149406; called by muse, mutect2, varscan2
- MACF1 | c.6713C>T p.T2238I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV57116198; called by muse, mutect2
- MAGEA12 | c.156G>C p.E52D | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.204); catalogued as COSV63294545; called by muse, mutect2
- MAGEA6 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as COSV61448878; called by muse, mutect2, varscan2
- MAGEH1 | c.596C>G p.S199W | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV61678755, COSV61679306; called by muse, mutect2, varscan2
- MAN2A1 | c.2231G>C p.G744A | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as COSV54850101, COSV54859734; called by muse, mutect2, varscan2
- MAP3K5 | c.3043A>G p.T1015A | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV62888540; called by muse, mutect2
- MAP7D3 | c.1499C>A p.S500Y | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60170579, COSV60171442; called by muse, mutect2, varscan2
- MBTPS2 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100810843; called by muse, mutect2, varscan2
- MCF2L2 | c.2449A>T p.K817* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as COSV61051810; called by muse, mutect2, varscan2
- MMP13 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52823551, COSV52824383; called by muse, mutect2
- MYH2 | c.326G>C p.R109P | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55435401, COSV55441385; called by muse, mutect2, varscan2
- MYO16 | c.2341G>T p.G781C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51786357; called by muse, mutect2, varscan2
- NEFM | c.2147A>T p.E716V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.527); catalogued as COSV55331508; called by muse, mutect2, varscan2
- NLGN1 | c.1198G>T p.V400L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV64329009; called by muse, mutect2, varscan2
- NOD2 | c.2771G>T p.G924V | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs104895453, CM020666, COSV56049569; called by muse, mutect2
- NTM | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66177081; called by muse, mutect2, varscan2
- OR10G7 | c.439A>T p.T147S | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV57866639; called by muse, mutect2
- OR2L8 | c.65T>A p.I22N | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.344); catalogued as COSV61726428; called by muse, mutect2
- OR4C11 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100155502; called by muse, mutect2, varscan2
- OR5L2 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV65723744; called by muse, mutect2, varscan2
- OR5W2 | c.653A>T p.Y218F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60615475; called by muse, mutect2, varscan2
- OR9Q2 | c.906G>C p.R302S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV61111721, COSV61112027; called by muse, mutect2
- PAGE5 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56943300; called by muse, mutect2
- PCDH11X | c.2411C>A p.S804Y | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.863); catalogued as COSV53455890; called by mutect2, varscan2
- PCDHA6 | c.1301C>A p.S434* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as COSV65343387, COSV65346338; called by muse, mutect2, varscan2
- PCK2 | c.1790C>T p.S597F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV53748415; called by muse, mutect2, varscan2
- PDE1B | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54490897, COSV54491804; called by muse, mutect2
- PDHA1 | c.260T>C p.I87T | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63327998; called by muse, mutect2, varscan2
- PDZD2 | c.7502A>C p.Y2501S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV56855586; called by muse, mutect2, varscan2
- PFKFB1 | c.993+1G>T p.X331_splice | Splice Site (SNP) | VAF 6/57 reads (11%) | catalogued as COSV66628076; called by muse, mutect2, varscan2
- PGBD2 | c.1764G>T p.E588D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV61399951; called by muse, mutect2, varscan2
- PIKFYVE | c.5723C>T p.T1908M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761036220, COSV52239458; called by muse, mutect2, varscan2
- PKD1L1 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV56962255; called by muse, mutect2, varscan2
- PLBD1 | c.639A>T p.K213N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV53692686; called by muse, mutect2, varscan2
- POLE2 | c.755+1G>C p.X252_splice | Splice Site (SNP) | VAF 8/48 reads (17%) | catalogued as COSV53559276; called by muse, mutect2
- POLE4 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.325); catalogued as rs199691810, COSV52051008; called by muse, mutect2, varscan2
- PRPS1 | c.739A>T p.I247F | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV65054263; called by muse, mutect2
- RALGAPA2 | c.1720A>G p.T574A | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV52493904; called by muse, mutect2
- RTL9 | c.2699C>A p.P900Q | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV71825492; called by muse, mutect2
- SEM1 | c.171G>T p.R57= | Splice Region (SNP) | VAF 5/31 reads (16%) | catalogued as COSV69740004; called by muse, mutect2
- SERPINA7 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.039); catalogued as COSV59665414; called by muse, mutect2, varscan2
- SH2D1A | c.192G>T p.W64C | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM1010332, COSV63578669, COSV63578834; called by muse, mutect2, varscan2
- SH3YL1 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1363596800, COSV62155961; called by muse, mutect2
- SLITRK2 | c.1978T>A p.L660I | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV59424494, COSV59427859; called by muse, mutect2, varscan2
- SLITRK4 | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV62023131; called by muse, mutect2, varscan2
- SMPD4 | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1253952104, COSV60079574; called by muse, mutect2
- SNX13 | c.1796A>G p.Y599C | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1457143488, COSV68064564; called by muse, mutect2
- SRPX2 | c.576G>T p.K192N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV65933428; called by muse, mutect2
- STK33 | c.1222G>C p.V408L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59399212; called by muse, mutect2
- TAF1 | c.4701T>A p.S1567R (on ENST00000373790 / NM_138923.4; = p.S1588R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52110942; called by muse, mutect2
- TAF1L | c.2054G>T p.R685L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs527429049, COSV54260322, COSV54266017; called by muse, mutect2, varscan2
- TBC1D8B | c.2386C>T p.L796F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.462); catalogued as COSV52177661; called by muse, mutect2, varscan2
- TDRD5 | c.1864G>T p.G622W | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99677045; called by muse, mutect2
- THBS2 | c.760T>C p.Y254H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV64678175; called by muse, mutect2, varscan2
- TLR8 | c.2309A>G p.H770R (on ENST00000218032 / NM_138636.5; = p.H788R on NM_016610.4) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54317276; called by muse, mutect2, varscan2
- TMEM8B | c.1245G>T p.M415I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.22); catalogued as COSV65076095, COSV65078269; called by muse, mutect2, varscan2
- TMPRSS9 | c.1342G>A p.E448K (on ENST00000648592; = p.E414K on NM_182973.2) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1466001057, COSV60226791; called by muse, mutect2, varscan2
- TTLL6 | c.2287C>A p.L763I (on ENST00000393382 / NM_001130918.3; = p.L456I on NM_173623.3) | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV64976759; called by muse, mutect2
- TTN | c.43649T>C p.I14550T (on ENST00000591111; = p.I7126T on NM_003319.4) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | PolyPhen benign (0.046); catalogued as rs372753303; called by muse, mutect2, varscan2
- UNC80 | c.408C>G p.D136E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.344); catalogued as COSV55887876; called by muse, mutect2
- USH2A | c.6721C>A p.P2241T | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs111033412, COSV56353238; called by muse, mutect2
- VPS41 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs1190856663, COSV56069524, COSV56071858; called by muse, mutect2
- VWCE | c.2807C>A p.T936N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV57111683; called by muse, mutect2, varscan2
- WDR7 | c.3840A>C p.R1280S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV54351175; called by muse, mutect2, varscan2
- WWC3 | c.1225C>A p.Q409K | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.117); catalogued as COSV66502413; called by muse, mutect2
- XIRP2 | c.6500C>A p.P2167Q (on ENST00000628543; = p.P2342Q on NM_152381.6) | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV54692724; called by muse, mutect2
- ZFHX4 | c.3651T>A p.Y1217* | Nonsense Mutation (SNP) | VAF 5/69 reads (7%) | catalogued as COSV50668872; called by muse, mutect2
- ZNF230 | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71273318; called by muse, mutect2, varscan2
- ZNF3 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.268); catalogued as COSV52795548; called by muse, mutect2, varscan2
- ZNF462 | c.5839C>G p.Q1947E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.047); catalogued as COSV52935033; called by muse, mutect2
- ZNF563 | c.1186A>T p.K396* | Nonsense Mutation (SNP) | VAF 10/170 reads (6%) | catalogued as COSV53370218; called by muse, mutect2
- ZNF584 | c.260G>T p.S87I | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.583); catalogued as COSV59722109; called by muse, mutect2
- GPRASP2 | c.591dup p.P198Tfs*6 | Frame Shift Ins (INS) | VAF 19/185 reads (10%) | called by mutect2, pindel, varscan2
- PLPPR1 | c.537del p.N180Tfs*9 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel, varscan2
- TBX4 | c.743del p.G248Dfs*22 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- TSSK1B | c.777del p.R260Gfs*142 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- ADGRE5 | c.2064T>C p.F688= (on ENST00000242786 / NM_078481.4; = p.F595= on NM_001784.5) | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV54391073; called by muse, mutect2
- AGBL1 | c.3162G>A p.L1054= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs1567115685; called by muse, mutect2
- ARFIP1 | c.141A>G p.Q47= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs749980564, COSV61884013; called by muse, mutect2, varscan2
- ATP11C | c.2112C>A p.T704= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV100558551; called by muse, mutect2
- ATP6V0E1 | c.93T>G p.G31= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV54184152; called by muse, mutect2
- BAZ1B | c.3504G>T p.L1168= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as rs781783517, COSV59990186; called by muse, mutect2
- CCDC87 | c.1947G>T p.V649= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV59578739; called by muse, mutect2
- CDKL5 | c.2226G>A p.E742= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV66110786; called by muse, mutect2, varscan2
- CNTN6 | c.237G>A p.L79= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs990543414, COSV63167967; called by muse, mutect2
- COL24A1 | c.4005A>G p.P1335= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV65304639; called by muse, mutect2, varscan2
- CSMD1 | c.3270C>A p.G1090= (on ENST00000520002; = p.G1089= on NM_033225.6) | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV59306541; called by muse, mutect2
- CTSL | c.840G>T p.V280= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV58246015; called by muse, mutect2, varscan2
- FABP5 | c.402A>G p.V134= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV51917243; called by muse, mutect2, varscan2
- FBN2 | c.4785C>T p.T1595= | Silent (SNP) | VAF 29/201 reads (14%) | catalogued as rs756084999, COSV52499961, COSV52505887; called by muse, mutect2, varscan2
- FGF1 | c.126G>T p.P42= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV61803598; called by muse, varscan2
- HGF | c.1212C>G p.S404= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV55947586; called by muse, mutect2
- ITPR1 | c.3207G>T p.T1069= (on ENST00000354582; = p.T1054= on NM_002222.7) | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV56976603; called by muse, mutect2, varscan2
- KCNJ5 | c.243G>T p.L81= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV57964826; called by muse, mutect2
- KIAA1109 | c.15017A>G p.*5006= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as rs1427095720, COSV52668349; called by muse, mutect2
- KMT2C | c.5826A>G p.T1942= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV51427186; called by muse, mutect2
- KRTAP10-6 | c.1011G>A p.T337= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as rs587720065, COSV59957609; called by muse, mutect2
- LGI2 | c.1320C>A p.I440= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as COSV66122710; called by muse, mutect2
- NLGN3 | c.360G>T p.P120= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100705034, COSV62442371; called by muse, mutect2, varscan2
- OR1D2 | c.138C>T p.I46= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV58921427; called by muse, mutect2, varscan2
- PRPS1 | c.738C>A p.A246= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV65054261; called by muse, mutect2
- RAC2 | c.297A>G p.P99= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV50774098; called by muse, mutect2, varscan2
- RASGRP4 | c.288C>G p.A96= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV53094974, COSV99498330; called by muse, mutect2, varscan2
- REG4 | c.210C>A p.I70= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs780857927, COSV56652796; called by muse, mutect2
- SCRIB | c.888C>T p.L296= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs1008813918, COSV57585097; called by muse, mutect2, varscan2
- SIGLEC12 | c.1302T>A p.P434= (on ENST00000291707 / NM_053003.4; = p.P316= on NM_033329.2) | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV52460777; called by muse, mutect2
- SLC12A2 | c.3360A>G p.Q1120= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV52470224; called by muse, mutect2, varscan2
- SPRY3 | c.111G>A p.Q37= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV57142490; called by muse, mutect2, varscan2
- WBP1L | c.495C>T p.S165= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV64009561; called by muse, mutect2
- WBP2NL | c.807G>A p.P269= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as rs1266718520, COSV60919080; called by muse, mutect2, varscan2
- ZNF560 | c.1902G>T p.G634= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as COSV56867038, COSV56867587; called by muse, mutect2
- KPNA4 | c.1032+471A>C | Intron (SNP) | VAF 16/178 reads (9%) | catalogued as COSV100515324; called by muse, mutect2
- SNORD116-1 | n.84G>C | RNA (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- SSPOP | n.8734G>T | RNA (SNP) | VAF 6/39 reads (15%) | catalogued as COSV65128790; called by mutect2, varscan2
- SSPOP | n.13699C>A | RNA (SNP) | VAF 6/42 reads (14%) | catalogued as COSV65128795; called by muse, mutect2, varscan2
- VPS11 | chr11:119069276 C>T | 5'Flank (SNP) | VAF 10/86 reads (12%) | catalogued as COSV56184636; called by muse, mutect2
